Somatic mutation profile of tumor specimen C3N-04173-01 (aliquot CPT0246080006) from CPTAC case C3N-04173, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.0 years (25,564 days).
Specimen C3N-04173-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ad2baf8-676e-4115-ba43-ad54c493ea91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04173-31 (Blood Derived Normal), aliquot CPT0246120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04acabb5-538d-4eae-898f-ba89c713d5ea

The open-access MAF lists 363 somatic variants for this specimen: 256 protein-altering or splice-affecting, 65 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 65, Nonsense Mutation 21, Intron 19, RNA 9, Splice Site 6, 3'UTR 5, 5'UTR 4, 5'Flank 4, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 25/238 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.375-2A>T p.X125_splice | Splice Site (SNP) | VAF 27/195 reads (14%) | hotspot (GDC flag); catalogued as CS044093, COSV58823384; called by muse, mutect2, varscan2
- ACE | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 29/341 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279450935; called by muse, mutect2
- ADAM7 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs763296638, COSV51541169; called by muse, mutect2
- ADCY5 | c.2450C>A p.P817H | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59201527; called by muse, mutect2, varscan2
- AGRN | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 60/482 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs576229011; called by muse, mutect2, varscan2
- ATP7B | c.3904-6C>T | Splice Region (SNP) | VAF 112/837 reads (13%) | catalogued as CS129467; called by muse, mutect2, varscan2
- BOC | c.2257C>G p.R753G | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56350935; called by muse, mutect2
- BPTF | c.4762A>G p.I1588V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771437944; called by muse, mutect2
- CACNA2D4 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV54950429; called by muse, mutect2, varscan2
- COX18 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs775857810; called by muse, mutect2, varscan2
- CSMD1 | c.7229A>T p.Y2410F (on ENST00000520002; = p.Y2409F on NM_033225.6) | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs778680657; called by muse, mutect2
- CTC1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 57/503 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1310610051, COSV59854510; called by muse, mutect2, varscan2
- CTNNA3 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1418585138; called by muse, mutect2, varscan2
- DARS2 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs764481820, COSV53406658; called by muse, mutect2, varscan2
- DNAH12 | c.6071G>T p.R2024L (on ENST00000351747; = p.R2043L on NM_001366028.2) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61058025; called by muse, mutect2
- DOK4 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV54674324; called by muse, mutect2
- EPHA6 | c.2572C>A p.R858= (on ENST00000389672 / NM_001080448.3; = p.R250= on NM_173655.4) | Splice Region (SNP) | VAF 22/243 reads (9%) | catalogued as rs369106551, COSV67597375; called by muse, mutect2
- GPATCH2 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 58/684 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as rs1179491232; called by muse, mutect2
- HDAC9 | c.3063G>T p.R1021S (on ENST00000441542 / NM_178425.3; = p.R1018S on NM_178423.3) | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV67783442; called by muse, mutect2, varscan2
- HEPHL1 | c.2678T>C p.V893A | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.304); catalogued as COSV59897267; called by muse, mutect2, varscan2
- HROB | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55369166; called by muse, mutect2, varscan2
- IBSP | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1017328338, COSV56897455; called by muse, mutect2
- IL16 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs1352768392; called by muse, mutect2
- IRF2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 32/329 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1364976757, COSV101165812; called by muse, mutect2, varscan2
- KCNH5 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1249534925; called by muse, mutect2, varscan2
- KEAP1 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50287198; called by muse, mutect2, varscan2
- KERA | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1017125971; called by muse, mutect2, varscan2
- KIRREL2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs1425331432; called by muse, mutect2
- KRT20 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51425625; called by muse, mutect2, varscan2
- LAMA1 | c.2965G>T p.A989S | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.021); catalogued as rs181556627, COSV67542112; called by muse, mutect2, varscan2
- LARP4B | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV60221494; called by muse, mutect2, varscan2
- LRFN5 | c.725T>G p.L242W | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1028728528, COSV99983270; called by muse, mutect2, varscan2
- MAGEB6 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV66872276, COSV66872702; called by muse, mutect2, varscan2
- MAP3K15 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV58829294; called by muse, mutect2, varscan2
- MEIS2 | c.677C>T p.S226L (on ENST00000561208 / NM_170675.5; = p.S213L on NM_002399.3) | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV54930671; called by muse, mutect2, varscan2
- METTL21C | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs140948695; called by muse, mutect2
- NELL1 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.833); catalogued as COSV54298176; called by muse, mutect2
- NEXMIF | c.4217C>A p.A1406E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs775633155; called by muse, mutect2, varscan2
- ODF2L | c.1161G>T p.L387F (on ENST00000317336; = p.L358F on NM_020729.3) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs926588033; called by muse, mutect2
- OR1J4 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as rs769279903, COSV61589868, COSV61590303; called by muse, mutect2, varscan2
- OR51S1 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV59058842; called by muse, mutect2
- PCDHA3 | c.1556C>A p.A519E | Missense Mutation (SNP) | VAF 115/1026 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs782212948; called by muse, mutect2, varscan2
- PCDHA6 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.334); catalogued as COSV65354020, COSV99061559; called by muse, mutect2, varscan2
- PCDHA9 | c.2378C>G p.S793* | Nonsense Mutation (SNP) | VAF 28/306 reads (9%) | catalogued as COSV100969671; called by muse, mutect2
- PCDHB4 | c.937T>A p.S313T | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs782308927, COSV52022912; called by muse, mutect2, varscan2
- PDE8A | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051627; called by muse, mutect2
- PDP1 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.182); catalogued as rs935020452; called by muse, mutect2, varscan2
- PPP1R26 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs753273862; called by muse, mutect2, varscan2
- PTPN4 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as rs1305257500; called by muse, mutect2, varscan2
- PTPRC | c.787A>T p.N263Y | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV61411658; called by muse, mutect2, varscan2
- PTPRO | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as rs1404748180, COSV55513448; called by muse, mutect2, varscan2
- RELN | c.3130G>T p.D1044Y | Missense Mutation (SNP) | VAF 56/578 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.753); catalogued as COSV59031950; called by muse, mutect2
- ROM1 | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 59/548 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1246812952; called by muse, mutect2, varscan2
- RPL11 | c.43C>T p.R15C (on ENST00000374550 / NM_001199802.1; = p.R16C on NM_000975.5) | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV104424061, COSV65778940; called by muse, mutect2
- RYR2 | c.8899G>C p.V2967L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100767002; called by muse, mutect2, varscan2
- SALL3 | c.2179G>A p.G727S | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as rs762027925, COSV73305838; called by muse, mutect2, varscan2
- SCNN1D | c.1118G>T p.G373V (on ENST00000338555; = p.G537V on NM_001130413.4) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100330222; called by muse, mutect2, varscan2
- SIGLEC11 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV101357074; called by muse, mutect2
- SLC12A5 | c.1559G>C p.G520A (on ENST00000454036 / NM_001134771.2; = p.G497A on NM_020708.5) | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54796023, COSV99715680; called by muse, mutect2, varscan2
- SMC2 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as rs761107909; called by muse, mutect2
- SPOP | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.22); catalogued as COSV61652660; called by muse, mutect2, varscan2
- SSTR3 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs556374239; called by muse, mutect2, varscan2
- TAF15 | c.1023A>T p.R341S (on ENST00000605844 / NM_139215.3; = p.R338S on NM_003487.4) | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.497); catalogued as rs1207328747; called by muse, mutect2, varscan2
- TBC1D16 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | catalogued as COSV60475570; called by muse, mutect2, varscan2
- TDP2 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1186961817; called by muse, mutect2, varscan2
- TGFBR3 | c.2216G>T p.W739L | Missense Mutation (SNP) | VAF 71/605 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769446254; called by muse, mutect2, varscan2
- TMEM106B | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101188830, COSV67543986; called by muse, mutect2
- TMEM117 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV56905440; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1062T>A p.D354E | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV99162168; called by muse, mutect2
- TRANK1 | c.3080C>T p.P1027L | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100083042; called by muse, mutect2, varscan2
- TRDMT1 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100003935, COSV58318386; called by muse, mutect2, varscan2
- TRHR | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 23/185 reads (12%) | catalogued as COSV61236389; called by muse, mutect2
- TSBP1 | c.1517C>A p.P506Q (on ENST00000617061; = p.P511Q on NM_006781.5) | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1259270429, COSV100898995; called by muse, mutect2, varscan2
- UAP1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV54851944; called by muse, mutect2, varscan2
- UGT3A2 | c.466del p.E156Rfs*36 | Frame Shift Del (DEL) | VAF 24/207 reads (12%) | catalogued as COSV56929380; called by mutect2, pindel, varscan2
- UMOD | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56776163; called by muse, mutect2, varscan2
- UNC79 | c.1304G>T p.R435L (on ENST00000393151 / NM_001346218.2; = p.R258L on NM_020818.5) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.441); catalogued as rs1419540000; called by muse, mutect2
- USH2A | c.3442C>A p.P1148T | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56351696, COSV56370553; called by muse, mutect2
- WNT7A | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs749815937; called by muse, mutect2, varscan2
- XKR3 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 45/377 reads (12%) | catalogued as COSV58887778; called by muse, mutect2, varscan2
- ZMAT3 | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 26/97 reads (27%) | catalogued as COSV60992276, COSV60994234; called by muse, mutect2, varscan2
- ZNF496 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99665498; called by muse, mutect2
- ZNF665 | c.1388G>A p.S463N (on ENST00000600412; = p.S528N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV67216550; called by muse, mutect2, varscan2
- ZSCAN31 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs774774868; called by muse, mutect2
- AADACL4 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCC4 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC011448.1 | c.725G>T p.W242L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAD9 | c.541A>G p.T181A | Missense Mutation (SNP) | VAF 57/488 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACVR1B | c.1229_1230del p.Y410Lfs*14 | Frame Shift Del (DEL) | VAF 50/438 reads (11%) | called by pindel, varscan2
- ADAMTS19 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.022); called by muse, mutect2
- ADAMTS20 | c.1312A>T p.M438L | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADGRA1 | c.1350C>A p.S450R | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AGPAT3 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- ALB | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 26/263 reads (10%) | called by muse, mutect2
- ANKRD26 | c.3046G>T p.A1016S | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANO4 | c.773C>G p.A258G (on ENST00000392977 / NM_001286615.2; = p.A223G on NM_178826.4) | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ANO5 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 40/384 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AOX1 | c.2138A>G p.H713R | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ARHGAP33 | c.1669G>T p.G557W | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- ASTN2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.203); called by muse, mutect2
- AUH | c.315A>C p.K105N | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- AUH | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B4GALT7 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- BARHL2 | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 50/614 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.543); called by muse, mutect2
- BCAS1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C2orf16 | c.225_227del p.K75_H76delinsN | In Frame Del (DEL) | VAF 15/138 reads (11%) | called by mutect2, pindel, varscan2
- CA1 | c.267C>A p.Y89* | Nonsense Mutation (SNP) | VAF 56/493 reads (11%) | called by muse, mutect2, varscan2
- CCDC102B | c.1263G>T p.Q421H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CCDC168 | c.16962A>T p.L5654F | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CCT8L2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- CD8B | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CDK4 | c.767C>A p.P256Q | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CDK5RAP1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- CDRT15L2 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CEBPA | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.047); called by muse, mutect2
- CLCN1 | c.640G>C p.A214P | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP1 | c.908T>A p.I303N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- CNTNAP4 | c.2941G>C p.G981R | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL11A1 | c.4517C>A p.P1506Q | Missense Mutation (SNP) | VAF 60/496 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL28A1 | c.708A>T p.E236D | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CRAMP1 | c.1966C>G p.P656A | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD1 | c.7840G>T p.E2614* (on ENST00000520002; = p.E2613* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- CSMD1 | c.5969G>T p.G1990V (on ENST00000520002; = p.G1989V on NM_033225.6) | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.7223C>A p.T2408K (on ENST00000297405 / NM_001363185.1; = p.T2304K on NM_052900.3) | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CYP2W1 | c.489C>G p.G163= | Splice Region (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- DGKD | c.2570A>G p.K857R (on ENST00000264057 / NM_152879.3; = p.K813R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2
- DGKQ | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DHX8 | c.2602A>G p.K868E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DICER1 | c.3755C>T p.S1252L | Missense Mutation (SNP) | VAF 53/495 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DLX4 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DSG1 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EHMT2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- EML1 | c.1674C>A p.F558L | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); called by muse, mutect2
- EPG5 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- EPHB1 | c.581A>T p.K194I | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETV1 | c.888_889insT p.G297Wfs*7 | Frame Shift Ins (INS) | VAF 28/234 reads (12%) | called by mutect2, pindel*, varscan2*
- FANCD2 | c.2014C>A p.P672T | Missense Mutation (SNP) | VAF 24/714 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.117); called by muse, mutect2
- FHOD3 | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2
- FUT7 | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 51/527 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2
- GABRG2 | c.1099C>T p.P367S (on ENST00000361925 / NM_001375343.1; = p.P327S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/551 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GATA5 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 42/312 reads (13%) | called by muse, mutect2, varscan2
- GLRA2 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR18 | c.905T>A p.L302Q | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIK3 | c.1405C>A p.L469M | Missense Mutation (SNP) | VAF 61/531 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- H2BC18 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 40/677 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); called by muse, mutect2
- HECTD3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2
- HMCN1 | c.8695A>T p.S2899C | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- HMMR | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.1); called by muse, mutect2
- HOOK2 | c.1698G>T p.E566D | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPA5 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- IL1R1 | c.1481A>G p.Q494R | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- ING3 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- INTS5 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- IQSEC1 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IRX1 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- KANK2 | c.2453A>C p.Q818P (on ENST00000586659 / NM_001379562.1; = p.Q826P on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- KCNU1 | c.20G>C p.R7P | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- KERA | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- KIF15 | c.4106A>T p.E1369V | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2
- KIF21A | c.2968dup p.E990Gfs*6 (on ENST00000361418 / NM_001378440.1; = p.E977Gfs*6 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/166 reads (14%) | called by mutect2, pindel, varscan2
- KMT2B | c.5567C>T p.A1856V | Missense Mutation (SNP) | VAF 55/384 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP24-1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KRTAP26-1 | c.167G>T p.C56F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.961); called by muse, mutect2
- LARS2 | c.1595G>T p.R532I | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP6 | c.3032A>G p.N1011S | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC69 | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRK2 | c.3347G>C p.G1116A | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LSM11 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- LSP1 | c.218del p.P73Lfs*66 | Frame Shift Del (DEL) | VAF 23/179 reads (13%) | called by mutect2, pindel, varscan2
- MAP3K19 | c.3436G>A p.G1146S | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPKBP1 | c.3716G>T p.G1239V (on ENST00000456763 / NM_001128608.2; = p.G1233V on NM_014994.3) | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- MARCHF6 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MEIOC | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- METTL22 | c.1180-2A>G p.X394_splice | Splice Site (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- MKRN3 | c.1129T>A p.W377R | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRPL53 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTF2 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MXRA5 | c.7601C>A p.T2534N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.402); called by mutect2, varscan2
- MYO10 | c.1260G>T p.R420S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MYO3B | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- NAA11 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NTNG1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 28/338 reads (8%) | called by muse, mutect2
- NYAP1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OGA | c.2204T>A p.M735K | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- OR14K1 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 153/479 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR2B3 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR2L2 | c.632C>A p.T211N | Missense Mutation (SNP) | VAF 118/452 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OR2L8 | c.511A>T p.R171W | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.337); called by muse, mutect2
- OR2T11 | c.784T>A p.F262I | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- OR2W3 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2
- OR4C15 | c.517T>A p.Y173N (on ENST00000314644; = p.Y119N on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR4C6 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 46/401 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR4F15 | c.369C>G p.Y123* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- OR4Q3 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.361); called by muse, mutect2
- OR51A4 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 76/610 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR5AS1 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- OR6B1 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2
- OTOP2 | c.552G>T p.W184C | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.5488C>A p.P1830T | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PCDHA6 | c.983C>A p.P328H | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PCDHB11 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PCDHGA1 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); called by muse, mutect2
- PCDHGB3 | c.409A>T p.I137F | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE6C | c.633+1G>T p.X211_splice | Splice Site (SNP) | VAF 56/483 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.2938del p.R980Gfs*52 (on ENST00000394691; = p.R1036Gfs*52 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 34/285 reads (12%) | called by mutect2, pindel, varscan2
- PLXNA1 | c.3982G>T p.A1328S | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PRF1 | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PRKG1 | c.1924T>G p.L642V | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRT | c.3877T>A p.S1293T | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.388); called by muse, mutect2
- RPRD2 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RPS4Y1 | c.424C>A p.H142N | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SCN1A | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SEC24C | c.2319C>A p.S773R | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- SERPINA4 | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SI | c.5198-1G>A p.X1733_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- SKA1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLC25A16 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC35C2 | c.272-1G>T p.X91_splice | Splice Site (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- SLC6A19 | c.1236G>T p.L412F | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SLC8A3 | c.2594T>A p.V865D (on ENST00000381269 / NM_183002.3; = p.V863D on NM_033262.4) | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC9A3R1 | c.659G>T p.R220M | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SLCO5A1 | c.1528T>C p.C510R | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SOX18 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SRCAP | c.2356T>C p.W786R | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STOML3 | c.342G>T p.Q114H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SYNE2 | c.3292C>G p.L1098V | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- TARS1 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TKTL2 | c.95G>A p.C32Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TLR9 | c.1946G>C p.R649P | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC6 | c.1712G>T p.W571L | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TMEM190 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 28/303 reads (9%) | called by muse, mutect2
- TMEM232 | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TNR | c.3365C>A p.S1122Y | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- TRBV4-1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 37/364 reads (10%) | called by muse, mutect2
- TRIM36 | c.2042A>T p.D681V | Missense Mutation (SNP) | VAF 21/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM58 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRIO | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TSPAN5 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBR1 | c.2036A>C p.Q679P | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- USP24 | c.4628C>G p.T1543S | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- USP37 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- VHLL | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- VIT | c.911T>C p.I304T (on ENST00000389975 / NM_001177969.1; = p.I319T on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWC2 | c.291G>T p.W97C | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- WDR64 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- XKR3 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- XPO1 | c.752_753insC p.Y252Lfs*2 | Frame Shift Ins (INS) | VAF 13/103 reads (13%) | called by mutect2, pindel
- ZFHX4 | c.10333A>C p.S3445R | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF273 | c.1375A>T p.K459* | Nonsense Mutation (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2
- ZNF518B | c.1309T>A p.S437T | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ZNF592 | c.500G>T p.S167I | Missense Mutation (SNP) | VAF 36/360 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZNF669 | c.978G>T p.R326S | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF717 | c.2315A>G p.N772S | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF800 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.2268C>T p.L756= | Silent (SNP) | VAF 36/459 reads (8%) | catalogued as COSV51419718; called by muse, mutect2
- ADCY5 | c.1869C>T p.G623= | Silent (SNP) | VAF 18/310 reads (6%) | catalogued as rs1192652461; called by muse, mutect2
- AIFM1 | c.144C>A p.L48= | Silent (SNP) | VAF 57/241 reads (24%) | called by muse, mutect2, varscan2
- ALMS1 | c.11592C>T p.A3864= | Silent (SNP) | VAF 43/304 reads (14%) | called by muse, mutect2, varscan2
- AMY1C | c.1086T>C p.Y362= | Silent (SNP) | VAF 32/794 reads (4%) | called by muse, mutect2
- ARHGAP33 | c.1668G>T p.L556= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- ATN1 | c.2421C>A p.A807= | Silent (SNP) | VAF 39/269 reads (14%) | catalogued as rs782397087; called by muse, mutect2, varscan2
- BCAR3 | c.2145G>T p.T715= | Silent (SNP) | VAF 24/227 reads (11%) | catalogued as rs747884735; called by muse, mutect2, varscan2
- BIRC6 | c.6297C>T p.V2099= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV101427841; called by muse, mutect2, varscan2
- CADPS | c.249C>T p.R83= | Silent (SNP) | VAF 29/199 reads (15%) | catalogued as rs1478007676; called by muse, mutect2, varscan2
- CAMTA1 | c.771G>A p.P257= | Silent (SNP) | VAF 39/297 reads (13%) | catalogued as rs746398137; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC168 | c.15774C>A p.I5258= | Silent (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2
- CDHR2 | c.1104C>A p.A368= | Silent (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2, varscan2
- CHPF2 | c.1260C>T p.P420= | Silent (SNP) | VAF 36/275 reads (13%) | called by muse, mutect2, varscan2
- COL5A1 | c.4725C>T p.P1575= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as rs767806664; called by muse, mutect2, varscan2
- CPN2 | c.69C>A p.P23= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV100102855; called by muse, mutect2, varscan2
- DHX33 | c.891G>T p.G297= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV56580147; called by muse, mutect2, varscan2
- ELOA2 | c.1626C>T p.D542= | Silent (SNP) | VAF 79/792 reads (10%) | catalogued as rs1422387788; called by muse, mutect2, varscan2
- FAT2 | c.3246C>T p.I1082= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- FIGN | c.66A>T p.P22= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- GYPC | c.162C>A p.P54= | Silent (SNP) | VAF 58/497 reads (12%) | catalogued as COSV52145773; called by muse, mutect2, varscan2
- HAUS5 | c.1128G>A p.L376= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- HSPA8 | c.873C>T p.I291= | Silent (SNP) | VAF 28/386 reads (7%) | catalogued as rs538018718; called by muse, mutect2
- INTS5 | c.828C>T p.F276= | Silent (SNP) | VAF 23/169 reads (14%) | catalogued as rs752655574; called by muse, mutect2, varscan2
- KATNBL1 | c.273A>T p.G91= | Silent (SNP) | VAF 37/375 reads (10%) | called by muse, mutect2, varscan2
- KCTD16 | c.933C>T p.S311= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as rs761142772; called by muse, mutect2, varscan2
- KDM5D | c.2754A>T p.L918= | Silent (SNP) | VAF 99/361 reads (27%) | called by muse, mutect2, varscan2
- LDHC | c.801T>C p.L267= | Silent (SNP) | VAF 38/387 reads (10%) | called by muse, mutect2
- LMTK3 | c.915C>T p.I305= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as COSV54317124; called by muse, mutect2, varscan2
- MS4A14 | c.36C>T p.H12= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs200092161; called by muse, mutect2, varscan2
- MYLIP | c.747C>T p.I249= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs374072017; called by muse, mutect2, varscan2
- MYO5C | c.2769G>T p.V923= | Silent (SNP) | VAF 24/221 reads (11%) | called by muse, mutect2, varscan2
- NLGN4X | c.729G>A p.G243= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs760293975, COSV52029123; called by muse, mutect2, varscan2
- NT5DC4 | c.609C>A p.I203= | Silent (SNP) | VAF 17/214 reads (8%) | catalogued as rs1209981683; called by muse, mutect2
- OR2M7 | c.93C>A p.V31= | Silent (SNP) | VAF 13/230 reads (6%) | called by muse, mutect2
- OR4S2 | c.189C>T p.F63= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV100412747; called by muse, mutect2, varscan2
- OR5D16 | c.324C>G p.T108= | Silent (SNP) | VAF 40/316 reads (13%) | catalogued as rs1270217515; called by muse, mutect2, varscan2
- OR5H15 | c.114C>A p.T38= | Silent (SNP) | VAF 43/447 reads (10%) | called by muse, mutect2, varscan2
- P2RY4 | c.9T>C p.S3= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1392G>T p.G464= | Silent (SNP) | VAF 54/370 reads (15%) | called by muse, mutect2, varscan2
- PCSK1N | c.6G>T p.A2= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- PHLDB1 | c.3165G>A p.L1055= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs782261861; called by muse, mutect2
- PHLPP1 | c.4602C>A p.A1534= | Silent (SNP) | VAF 22/256 reads (9%) | catalogued as rs1370470390; called by muse, mutect2
- PRKDC | c.5511A>G p.R1837= | Silent (SNP) | VAF 35/266 reads (13%) | catalogued as rs758203231; called by muse, mutect2, varscan2
- R3HDML | c.339G>A p.L113= | Silent (SNP) | VAF 19/191 reads (10%) | called by muse, mutect2
- ROS1 | c.6882C>A p.S2294= | Silent (SNP) | VAF 44/421 reads (10%) | called by muse, mutect2, varscan2
- SCN8A | c.102C>G p.L34= | Silent (SNP) | VAF 50/370 reads (14%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3732G>T p.L1244= | Silent (SNP) | VAF 55/546 reads (10%) | called by muse, mutect2, varscan2
- SLC9A2 | c.1878C>A p.A626= | Silent (SNP) | VAF 32/217 reads (15%) | catalogued as rs202139053; called by muse, mutect2, varscan2
- SNRPA | c.384G>T p.G128= | Silent (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- SPATA20 | c.243G>C p.V81= (on ENST00000356488 / NM_001258372.1; = p.V97= on NM_022827.4) | Silent (SNP) | VAF 32/194 reads (16%) | called by muse, mutect2, varscan2
- SUPT16H | c.306C>T p.A102= | Silent (SNP) | VAF 21/213 reads (10%) | called by muse, mutect2
- TENM2 | c.3957C>T p.T1319= (on ENST00000518659 / NM_001122679.2; = p.T1080= on NM_001080428.3) | Silent (SNP) | VAF 76/711 reads (11%) | catalogued as rs941124267; called by muse, mutect2, varscan2
- TEX44 | c.750C>T p.H250= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as rs777837940, COSV58354563; called by muse, mutect2, varscan2
- TMTC3 | c.2244T>C p.N748= | Silent (SNP) | VAF 30/212 reads (14%) | called by muse, mutect2, varscan2
- TRIM27 | c.396C>G p.L132= | Silent (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2
- TRIM71 | c.1335G>A p.K445= | Silent (SNP) | VAF 24/229 reads (10%) | catalogued as rs758791413; called by muse, mutect2, varscan2
- UBE3B | c.1713G>T p.V571= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- ZBED5 | c.1962A>G p.T654= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- ZDHHC8 | c.267G>T p.P89= | Silent (SNP) | VAF 21/187 reads (11%) | catalogued as COSV100272764; called by muse, mutect2, varscan2
- ZEB2 | c.2151C>A p.P717= | Silent (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7842G>T p.P2614= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV51457640, COSV99260068; called by muse, mutect2, varscan2
- ZNF148 | c.1116A>C p.S372= | Silent (SNP) | VAF 32/362 reads (9%) | called by muse, mutect2
- ZNF17 | c.1545A>G p.T515= | Silent (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- ZNF445 | c.882G>C p.L294= | Silent (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- ACTN2 | c.698-1137G>T | Intron (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2, varscan2
- ADH1C | c.*6T>A | 3'UTR (SNP) | VAF 28/247 reads (11%) | catalogued as COSV101575515; called by muse, mutect2, varscan2
- AL355922.1 | n.81T>A | RNA (SNP) | VAF 46/319 reads (14%) | called by muse, mutect2, varscan2
- ANKRD36 | c.-11A>T | 5'UTR (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- AURKC | c.58+30G>A | Intron (SNP) | VAF 55/397 reads (14%) | catalogued as COSV100248963; called by muse, mutect2, varscan2
- C18orf54 | c.589+263A>G | Intron (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- C5orf66-AS2 | n.775G>T | RNA (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2
- C8B | c.*37C>A | 3'UTR (SNP) | VAF 43/347 reads (12%) | called by muse, mutect2, varscan2
- CYBC1 | c.*321C>T | 3'UTR (SNP) | VAF 59/475 reads (12%) | called by muse, varscan2
- DAPK2 | c.858+1541G>C | Intron (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- DCLRE1CP1 | n.305C>A | RNA (SNP) | VAF 62/624 reads (10%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53153102 G>A | 5'Flank (SNP) | VAF 20/152 reads (13%) | catalogued as rs1432776045; called by muse, mutect2, varscan2
- FAM183A | chr1:43145231 del C | 5'Flank (DEL) | VAF 24/188 reads (13%) | called by mutect2, pindel, varscan2
- FAM90A25P | n.753C>A | RNA (SNP) | VAF 127/2568 reads (5%) | called by muse, mutect2
- FANCM | c.681+18C>T | Intron (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2
- FBXO46 | c.*308A>G | 3'UTR (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- GOLGA2 | c.171+1041G>T | Intron (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.497C>A | RNA (SNP) | VAF 38/357 reads (11%) | catalogued as rs1479031563; called by muse, mutect2, varscan2
- KLRA1P | n.673G>A | RNA (SNP) | VAF 14/116 reads (12%) | catalogued as rs1400206173; called by muse, mutect2, varscan2
- LINC02118 | n.164C>A | RNA (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-5703C>T | Intron (SNP) | VAF 106/425 reads (25%) | catalogued as rs1314272336, COSV99962789; called by muse, mutect2, varscan2
- MED13L | c.-25C>A | 5'UTR (SNP) | VAF 40/286 reads (14%) | called by muse, varscan2
- MTHFS | c.117+49G>C | Intron (SNP) | VAF 28/300 reads (9%) | catalogued as rs758826459; called by muse, mutect2
- MTR | c.503-1049A>C | Intron (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- NKAIN4 | c.54+256A>T | Intron (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- OR51F5P | n.109T>A | RNA (SNP) | VAF 31/277 reads (11%) | called by muse, mutect2, varscan2
- POTEH | c.922-1057G>T | Intron (SNP) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- PPM1K | c.542-2172del | Intron (DEL) | VAF 26/259 reads (10%) | called by mutect2, varscan2
- PPP2R5C | c.1443+3157G>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- PRKCB | c.1066-2850T>G | Intron (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- PRND | chr20:4732607 A>T | 3'Flank (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- PTPRD | c.3989-526G>A | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- REG3A | c.*1T>C | 3'UTR (SNP) | VAF 20/229 reads (9%) | called by muse, mutect2
- RHD | c.-27G>A | 5'UTR (SNP) | VAF 34/534 reads (6%) | catalogued as COSV100155160; called by muse, mutect2
- RN7SL214P | chr15:77919033 T>C | 5'Flank (SNP) | VAF 112/918 reads (12%) | called by muse, varscan2
- SCUBE1 | c.844+36T>C | Intron (SNP) | VAF 40/352 reads (11%) | catalogued as rs993244565; called by muse, mutect2, varscan2
- SPARC | c.209-35G>T | Intron (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.1095C>A | RNA (SNP) | VAF 35/306 reads (11%) | catalogued as rs761367233; called by muse, mutect2, varscan2
- SPOP | c.480+426C>G | Intron (SNP) | VAF 12/125 reads (10%) | catalogued as rs774505830; called by muse, mutect2, varscan2
- TMEM175 | c.192+71C>T | Intron (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- UNC80 | c.-10dup | 5'UTR (INS) | VAF 48/420 reads (11%) | called by pindel, varscan2
- ZEB2 | chr2:144520045 G>A | 5'Flank (SNP) | VAF 52/418 reads (12%) | catalogued as rs1382207294; called by muse, mutect2, varscan2
